Gene-level copy-number profile of tumor specimen TCGA-29-1775-01A from TCGA case TCGA-29-1775, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 51.9 years (18,943 days).
Specimen TCGA-29-1775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ae4de736-1f04-4b8d-bc66-f8389cc74b9f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1775-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/716f9c95-900a-445c-b05a-8a459fd844da

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,398; copy number 2: 17,520; copy number 3: 15,395; copy number 4: 17,252; copy number 5: 4,417; copy number 6: 1,576; copy number 7: 1,413; copy number 8: 241; copy number 9: 49; copy number 10: 168; copy number 12: 363; copy number 13: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1775-01A-01D-0577-01): tumor purity 0.91, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:41,557,027–41,630,908, 3 genes: ELOCP2, TYRO3, AC016134.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 598 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,884,459–151,125,542, 64 genes, copy number 9–10 (within-gene range 3–10) (broad region; genes not listed).
- chr8:53,712,697–56,993,867, 63 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).
- chr19:15,107,401–24,163,425, 464 genes, copy number 10–12 (broad region; genes not listed).
- chr20:13,368,291–13,996,443, 7 genes, copy number 10 (within-gene range 6–10): AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.

Autosomal genes at a single copy (total copy number 1): 1,398. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
